Somatic mutation profile of tumor specimen 0DFJKT from CCDI case PBBRIE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic liposarcoma; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.2 years (5,904 days).
Specimen 0DFJKT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43cf99a0-4cf6-4dac-8ea3-ca1b070c74f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFJJ4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baef5a07-ff8a-4289-9c54-e3716214bed8

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Nonsense Mutation 1, Splice Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>C p.X125_splice | Splice Site (SNP) | VAF 18/75 reads (24%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- FAM83B | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs376811005; called by muse, mutect2, varscan2
- MEAF6 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV56163711; called by muse, mutect2, varscan2
- SNTB2 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1363254881, COSV100293650; called by muse, mutect2
- TBC1D10A | c.1272G>C p.K424N | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.879); catalogued as COSV53163604; called by muse, mutect2, varscan2
- GLB1L3 | c.1725C>A p.Y575* | Nonsense Mutation (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- LRP1B | c.7500C>A p.D2500E | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- NR0B2 | c.730G>T p.V244F | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OR13G1 | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by mutect2, varscan2
- RAB3GAP1 | c.2672G>T p.G891V | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2
- C3 | c.840G>A p.Q280= | Silent (SNP) | VAF 70/254 reads (28%) | called by muse, mutect2, varscan2
- FAM135B | c.477C>T p.F159= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as rs866950058, COSV99358370; called by muse, mutect2
- NAP1L2 | c.792T>G p.P264= | Silent (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- RESF1 | c.4476G>A p.G1492= | Silent (SNP) | VAF 26/399 reads (7%) | called by muse, mutect2
- SMYD4 | c.1737G>C p.R579= | Silent (SNP) | VAF 237/553 reads (43%) | called by muse, mutect2, varscan2
- WASHC4 | c.2388C>T p.Y796= | Silent (SNP) | VAF 30/572 reads (5%) | called by muse, mutect2
- A1BG | c.614-39del | Intron (DEL) | VAF 7/50 reads (14%) | called by mutect2, varscan2
- ARL17A | c.*3874G>A | 3'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as rs200195412, COSV60235811; called by mutect2, varscan2
